Somatic mutation profile of tumor specimen MP2PRT-PATYBE-TMP1-A (aliquot MP2PRT-PATYBE-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATYBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (839 days).
Specimen MP2PRT-PATYBE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bdc040c-898a-4109-805b-fc9b94557b24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYBE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYBE-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca7d3e79-b181-4d18-8681-370fc9411e3a

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFPT2 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 198/550 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV53806643; called by muse, mutect2, varscan2
- GJD2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 16/555 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs995766804, COSV51747367; called by muse, mutect2
- KSR2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 143/377 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs889640480; called by muse, mutect2, varscan2
- MTRNR2L5 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 92/205 reads (45%) | PolyPhen benign (0); catalogued as rs999299946; called by muse, mutect2, varscan2
- CD2BP2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 175/443 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CDH18 | c.1090T>G p.F364V | Missense Mutation (SNP) | VAF 146/387 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ETF1 | c.331A>G p.N111D | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CNTNAP2 | c.1512G>A p.Q504= | Silent (SNP) | VAF 77/192 reads (40%) | called by muse, mutect2, varscan2
- COLGALT1 | c.1605C>T p.S535= | Silent (SNP) | VAF 116/292 reads (40%) | catalogued as rs778596520; called by muse, mutect2, varscan2
- KMT2B | c.3108T>C p.P1036= | Silent (SNP) | VAF 172/423 reads (41%) | called by muse, varscan2
- ANXA8L1 | chr10:46373439 G>A | 5'Flank (SNP) | VAF 97/352 reads (28%) | called by muse, mutect2, varscan2
- IGLV5-45 | chr22:22376505 ins CC | 3'Flank (INS) | VAF 104/277 reads (38%) | called by mutect2, pindel, varscan2
